Somatic mutation profile of tumor specimen TCGA-A3-3374-01A (aliquot TCGA-A3-3374-01A-01W-0886-08) from TCGA case TCGA-A3-3374, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.7 years (18,890 days).
Specimen TCGA-A3-3374-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09ff4566-4382-4f68-9ff3-82128187affb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3374-11A (Solid Tissue Normal), aliquot TCGA-A3-3374-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57bfd5da-bbe7-45f9-8ce2-99b40d1830dc

The open-access MAF lists 149 somatic variants for this specimen: 125 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 102, Silent 24, Nonsense Mutation 15, Frame Shift Ins 4, Splice Site 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- A1CF | c.1139G>T p.R380I | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV50957123; called by muse, mutect2
- ABCC1 | c.2026G>T p.V676L | Missense Mutation (SNP) | VAF 28/748 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV60680072, COSV60690970; called by muse, mutect2
- ACIN1 | c.2806G>T p.E936* | Nonsense Mutation (SNP) | VAF 108/1052 reads (10%) | catalogued as COSV52973174; called by muse, mutect2, varscan2
- ADCY10 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 24/202 reads (12%) | catalogued as COSV63238494; called by muse, mutect2, varscan2
- ADCY3 | c.2278C>A p.L760M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.666); catalogued as COSV53164254; called by muse, mutect2, varscan2
- ADGRG6 | c.2827G>C p.A943P | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51586302; called by muse, mutect2
- ADGRL2 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV54651687; called by muse, mutect2, varscan2
- AGAP3 | c.2105C>T p.A702V (on ENST00000622464; = p.A738V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV68243207; called by muse, mutect2, varscan2
- AKAP9 | c.11426G>A p.W3809* (on ENST00000359028; = p.W3785* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 82/186 reads (44%) | catalogued as COSV62338511; called by muse, mutect2, varscan2
- ALB | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV55735731; called by muse, mutect2
- AP4B1 | c.1990G>T p.V664L | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as COSV56723225; called by muse, mutect2
- APOL6 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV68749369; called by muse, mutect2, varscan2
- ATG13 | c.1215G>C p.E405D (on ENST00000359513 / NM_001346321.1; = p.E368D on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 165/282 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV56317387; called by muse, mutect2, varscan2
- C14orf93 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 190/258 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1445473905, COSV54440283; called by muse, mutect2, varscan2
- CA14 | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as rs1553849024, COSV52528189; called by muse, mutect2, varscan2
- CCDC113 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54685017; called by muse, mutect2
- CHIA | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV58473526; called by muse, mutect2, varscan2
- CNOT7 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV61352490; called by muse, mutect2, varscan2
- COL6A3 | c.7792G>A p.G2598R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55079510; called by muse, mutect2
- CPA5 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV62568721; called by muse, mutect2, varscan2
- CRACD | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51714975; called by muse, mutect2
- CST5 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 248/2031 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV59013785; called by muse, mutect2, varscan2
- CUX2 | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55624127; called by muse, mutect2, varscan2
- CXorf58 | c.221T>C p.F74S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV64857805; called by muse, varscan2
- CYP2R1 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 72/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104402369, COSV58126606; called by muse, mutect2, varscan2
- DALRD3 | c.1034C>T p.A345V (on ENST00000341949 / NM_001009996.3; = p.A178V on NM_018114.5) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1211877961, COSV58243885; called by muse, mutect2
- DCAF4 | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 22/557 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62318974, COSV62320023; called by muse, mutect2
- DDX60 | c.992G>T p.R331I | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67095019; called by muse, mutect2
- DNAH3 | c.3737G>T p.W1246L | Missense Mutation (SNP) | VAF 32/666 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54502854; called by muse, mutect2
- DNAH9 | c.10798C>A p.Q3600K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs756440719, COSV52333602; called by muse, mutect2, varscan2
- DTX1 | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV55653737; called by muse, mutect2
- DYNC1H1 | c.9617G>T p.R3206M | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV64134276; called by muse, mutect2, varscan2
- ELF4 | c.1465C>A p.L489I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV57451378; called by muse, mutect2
- EPB42 | c.1876C>A p.L626M (on ENST00000441366 / NM_001114134.2; = p.L656M on NM_000119.3) | Missense Mutation (SNP) | VAF 36/1438 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as COSV55748468; called by muse, mutect2
- EPHA5 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as COSV56630678; called by muse, mutect2, varscan2
- ETAA1 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55471982; called by muse, mutect2
- FAM47C | c.2381G>T p.R794L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV63723565, COSV63725228; called by muse, mutect2, varscan2
- FCHSD1 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV71300509, COSV71300745; called by muse, mutect2
- FRAS1 | c.2947C>A p.Q983K | Missense Mutation (SNP) | VAF 142/1426 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as COSV53588538; called by muse, mutect2, varscan2
- FRYL | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV51939399; called by muse, mutect2, varscan2
- FTCD | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1156490854, COSV52423062; called by muse, mutect2, varscan2
- GGCX | c.1326C>A p.D442E | Missense Mutation (SNP) | VAF 303/2140 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52087063, COSV52090108; called by muse, varscan2
- GPRC5B | c.79G>C p.A27P | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.296); catalogued as COSV56025053; called by muse, mutect2
- GRIA1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as rs750421563, COSV53588586; called by muse, mutect2, varscan2
- HLA-DPB1 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV69602269, COSV69603632; called by muse, mutect2, varscan2
- HSPA2 | c.1162T>C p.S388P | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as COSV55968691; called by muse, mutect2
- HYDIN | c.2485C>A p.L829I | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58551222; called by muse, mutect2
- IRF5 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs144448991; called by muse, mutect2, varscan2
- ITLN2 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV63537352; called by muse, mutect2
- KBTBD7 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65266046; called by muse, mutect2, varscan2
- KIF23 | c.2312C>A p.T771N | Missense Mutation (SNP) | VAF 20/656 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52977191; called by muse, mutect2
- KLHDC7A | c.2176T>C p.Y726H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.533); catalogued as COSV68768951; called by muse, mutect2
- KRT72 | c.1460G>T p.S487I | Missense Mutation (SNP) | VAF 42/1507 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV53373145; called by muse, mutect2
- LILRA1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as rs759678804, COSV52177807; called by muse, mutect2, varscan2
- LRBA | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); catalogued as COSV63949715; called by muse, mutect2, varscan2
- MIGA2 | c.1385C>A p.S462* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV52977640; called by muse, mutect2
- MMS22L | c.3408C>A p.N1136K | Missense Mutation (SNP) | VAF 170/613 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs768300995, COSV51516614; called by muse, mutect2, varscan2
- MTCL1 | c.4904C>A p.T1635K (on ENST00000306329 / NM_001378206.1; = p.T1316K on NM_015210.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60403076; called by muse, mutect2, varscan2
- MYH7 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 28/936 reads (3%) | catalogued as COSV62516208; called by muse, mutect2
- MYOM1 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 70/454 reads (15%) | catalogued as COSV55285349; called by muse, mutect2, varscan2
- NAV1 | c.3535C>A p.Q1179K | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55213969; called by muse, mutect2, varscan2
- NAV2 | c.5113G>A p.E1705K (on ENST00000396087 / NM_001244963.2; = p.E1649K on NM_145117.5) | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100217508; called by muse, varscan2
- NDN | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100086233, COSV59358388, COSV59359664; called by muse, varscan2
- NFYC | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.7); catalogued as rs866880681; called by muse, mutect2
- NOTCH2 | c.4548C>A p.N1516K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV56681319; called by muse, mutect2, varscan2
- NUP188 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65360195; called by muse, mutect2
- OCA2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 101/385 reads (26%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.693); catalogued as rs749410903, COSV62338286; called by muse, mutect2, varscan2
- OR11L1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV63313571; called by muse, mutect2
- OR52B6 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61447164; called by muse, mutect2, varscan2
- OR7G2 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59687291; called by muse, mutect2
- PARP3 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV51752878; called by muse, mutect2
- PGBD2 | c.1699C>T p.H567Y | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV61399576; called by muse, mutect2
- PKHD1L1 | c.12310G>T p.V4104L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV65736898; called by muse, mutect2, varscan2
- PLAG1 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57609171; called by muse, mutect2, varscan2
- PLCL1 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101407238, COSV70820920; called by muse, mutect2, varscan2
- PLXND1 | c.5692G>A p.A1898T | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV60709235; called by muse, mutect2
- PRAMEF1 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 152/1032 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.052); catalogued as rs199886880; called by muse, mutect2, varscan2
- PRUNE2 | c.8632G>T p.D2878Y | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56313950; called by muse, mutect2
- PTRHD1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 17/208 reads (8%) | catalogued as COSV53229268; called by muse, mutect2
- RAB11FIP4 | c.232dup p.V78Gfs*46 | Frame Shift Ins (INS) | VAF 11/91 reads (12%) | catalogued as rs751772020; called by mutect2, pindel, varscan2
- RARB | c.526G>T p.E176* (on ENST00000383772 / NM_001290216.2; = p.E169* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV58064757, COSV58066615; called by muse, mutect2
- RBM19 | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55688019; called by muse, mutect2, varscan2
- RCSD1 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 160/1208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63257801; called by muse, mutect2, varscan2
- RIPPLY1 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52173532; called by muse, mutect2
- SCN1A | c.1788C>A p.S596R | Missense Mutation (SNP) | VAF 60/537 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV57659496; called by muse, mutect2, varscan2
- SCN5A | c.4758C>A p.Y1586* (on ENST00000333535 / NM_198056.3; = p.Y1585* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 64/656 reads (10%) | catalogued as COSV61115530; called by muse, mutect2
- SEC16A | c.2909C>T p.A970V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV51521430; called by muse, mutect2, varscan2
- SERINC1 | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV60101412; called by muse, mutect2, varscan2
- SLC25A21 | c.331-1G>C p.X111_splice | Splice Site (SNP) | VAF 25/79 reads (32%) | catalogued as COSV58714481; called by muse, mutect2, varscan2
- SLC36A1 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 26/611 reads (4%) | catalogued as COSV54652040; called by muse, mutect2
- SLC45A1 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV57092811; called by muse, mutect2
- SLC4A11 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV66260284; called by muse, mutect2
- SLITRK5 | c.2759dup p.S921Efs*22 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | catalogued as rs746043874; called by mutect2, pindel
- SPOCD1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.472); catalogued as COSV57093695; called by muse, mutect2, varscan2
- STAT6 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 61/598 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as COSV55668940; called by muse, mutect2, varscan2
- STYXL1 | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV50387862; called by muse, mutect2
- SYNE1 | c.8200C>A p.Q2734K (on ENST00000367255 / NM_182961.4; = p.Q2741K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54904437, COSV99554752; called by muse, mutect2
- TADA1 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 14/129 reads (11%) | catalogued as COSV63309827; called by muse, mutect2, varscan2
- TAGAP | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1217339653, COSV57850461; called by muse, mutect2, varscan2
- TENT4A | c.1988C>A p.S663Y | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV50094343; called by muse, mutect2
- TMEM131 | c.3480C>A p.N1160K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV51769895, COSV99487574; called by muse, mutect2, varscan2
- TMTC4 | c.622C>A p.L208M (on ENST00000376234 / NM_001350577.2; = p.L227M on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV60891289; called by muse, varscan2
- TRIM31 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 126/474 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV65059340; called by muse, mutect2, varscan2
- TRMT12 | c.444C>G p.F148L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV60776513; called by muse, mutect2
- TSC2 | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54755938; called by muse, varscan2
- UGT2B7 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59441874; called by muse, mutect2
- USP11 | c.1954G>T p.D652Y (on ENST00000218348; = p.D609Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV54472335; called by muse, mutect2
- YTHDF2 | c.453C>G p.S151R | Missense Mutation (SNP) | VAF 216/359 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV65722740; called by muse, mutect2, varscan2
- ZNF148 | c.1407G>T p.Q469H | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62302158; called by muse, mutect2
- ZNF236 | c.2855G>A p.G952D | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1319065832, COSV53482099; called by muse, mutect2, varscan2
- ZNF462 | c.2158G>T p.V720F | Missense Mutation (SNP) | VAF 68/728 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV52930102; called by muse, mutect2
- ZNF740 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV57237705; called by muse, mutect2, varscan2
- C12orf4 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- CIZ1 | c.1478A>G p.D493G | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by mutect2, varscan2
- CORIN | c.1589+2T>C p.X530_splice | Splice Site (SNP) | VAF 27/100 reads (27%) | called by mutect2, varscan2
- EML5 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FRY | c.6743_6757del p.S2248_Y2252del | In Frame Del (DEL) | VAF 47/163 reads (29%) | called by mutect2*, pindel
- MYO19 | c.1804C>A p.L602M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NARF | c.881_883del p.S294_S295delinsT | In Frame Del (DEL) | VAF 108/229 reads (47%) | called by pindel, varscan2
- NUP85 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- REV3L | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2
- SCMH1 | c.537G>T p.K179N (on ENST00000326197 / NM_001031694.2; = p.K132N on NM_012236.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2
- VPS13C | c.3399dup p.V1134Cfs*5 (on ENST00000644861 / NM_020821.3; = p.V1091Cfs*5 on NM_017684.5) | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- ZNF14 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ANGPT1 | c.1314A>G p.K438= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1169426289, COSV52430426; called by muse, mutect2, varscan2
- ATXN7L2 | c.1251G>T p.G417= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV60203858; called by muse, mutect2
- BLK | c.759C>A p.G253= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV52049387; called by muse, mutect2, varscan2
- CPXM2 | c.1944G>T p.V648= | Silent (SNP) | VAF 12/300 reads (4%) | catalogued as COSV53856010; called by muse, mutect2
- EOGT | c.1455G>A p.L485= (on ENST00000383701 / NM_001278689.2; = p.L401= on NM_173654.3) | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV55149286; called by muse, mutect2
- GNL1 | c.1083G>A p.V361= | Silent (SNP) | VAF 29/298 reads (10%) | catalogued as COSV64835046; called by muse, mutect2, varscan2
- ITCH | c.249G>T p.V83= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV52929207; called by muse, varscan2
- KCNG4 | c.186G>A p.L62= | Silent (SNP) | VAF 47/274 reads (17%) | catalogued as COSV57582636; called by muse, mutect2, varscan2
- KIF19 | c.1068C>T p.N356= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1449886567, COSV63428777; called by muse, mutect2
- KLHL6 | c.1659C>A p.I553= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as rs753728391, COSV100384847, COSV58064477; called by muse, mutect2, varscan2
- NAV2 | c.5112G>A p.Q1704= (on ENST00000396087 / NM_001244963.2; = p.Q1648= on NM_145117.5) | Silent (SNP) | VAF 36/160 reads (23%) | called by muse, varscan2
- NAV2 | c.5142G>A p.L1714= (on ENST00000396087 / NM_001244963.2; = p.L1658= on NM_145117.5) | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV60656382; called by muse, varscan2
- NELL2 | c.1620G>A p.V540= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as rs759488799, COSV61568780; called by muse, mutect2, varscan2
- OR9G4 | c.384C>T p.N128= | Silent (SNP) | VAF 50/324 reads (15%) | catalogued as COSV57247637; called by muse, mutect2, varscan2
- PCDHB4 | c.1335C>T p.D445= | Silent (SNP) | VAF 55/263 reads (21%) | catalogued as COSV52021589; called by muse, mutect2, varscan2
- PLXNB3 | c.2116C>A p.R706= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV62797243; called by muse, mutect2, varscan2
- PSPC1 | c.657G>T p.G219= | Silent (SNP) | VAF 94/848 reads (11%) | catalogued as COSV58886449; called by muse, mutect2, varscan2
- RET | c.1068G>T p.L356= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV60686690; called by muse, mutect2, varscan2
- SETX | c.6483A>G p.L2161= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV56378718; called by muse, mutect2, varscan2
- SORCS3 | c.2625C>T p.I875= | Silent (SNP) | VAF 98/162 reads (60%) | catalogued as rs775261134, COSV100863404, COSV63793264, COSV63794690; called by muse, mutect2, varscan2
- TANGO6 | c.2259C>A p.A753= | Silent (SNP) | VAF 74/529 reads (14%) | catalogued as COSV55760150; called by muse, mutect2, varscan2
- TCOF1 | c.1764C>T p.P588= (on ENST00000377797 / NM_001135243.1; = p.P511= on NM_000356.4) | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV60345441; called by muse, mutect2, varscan2
- TLR4 | c.246G>A p.V82= (on ENST00000355622 / NM_138554.5; = p.V42= on NM_003266.4) | Silent (SNP) | VAF 66/504 reads (13%) | catalogued as rs78293159, COSV62922414; called by muse, mutect2, varscan2
- TXNIP | c.876G>A p.L292= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV65219934; called by muse, mutect2
